Gene-level copy-number profile of tumor specimen TCGA-ZP-A9CZ-01A from TCGA case TCGA-ZP-A9CZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G1; Age at diagnosis: 72.3 years (26,403 days).
Specimen TCGA-ZP-A9CZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.186c68e5-d5ae-4cb3-a94e-627f4bc4e7f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZP-A9CZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bbea4c70-b055-45ae-83ef-4193931d46e0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 9,232; copy number 2: 44,891; copy number 3: 5,018; copy number 4: 624; copy number 5: 47.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZP-A9CZ-01A-11D-A381-01): tumor purity 0.67, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:132,725,578–132,946,874, 4 genes (within-gene range 0–1): AK8, AL445645.1, SPACA9, TSC1.
- chr9:132,945,707–132,963,793, 3 genes: MIR548AW, AL593851.1, RNU7-21P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 47 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,295,068, 47 genes, copy number 5 (within-gene range 3–5): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.

Autosomal genes at a single copy (total copy number 1): 6,845. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
